Somatic mutation profile of tumor specimen TARGET-20-PASXYG-09A (aliquot TARGET-20-PASXYG-09A-02D) from TARGET case TARGET-20-PASXYG, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 11.2 years (4,103 days).
Specimen TARGET-20-PASXYG-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3c003835-d5f1-4a34-8159-caf4472f8f62.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASXYG-14A (Bone Marrow Normal), aliquot TARGET-20-PASXYG-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/60531999-dd20-4444-a4f7-8d64b2a8be8c

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 2, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FOXP2 | c.2039C>A p.A680E | Missense Mutation (SNP) | VAF 77/199 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.069); catalogued as COSV63488822; called by muse, mutect2, varscan2
- ASXL2 | c.1194_1195insTTCACTT p.P399Ffs*11 | Frame Shift Ins (INS) | VAF 81/231 reads (35%) | called by mutect2, pindel, varscan2
- TADA1 | c.202dup p.T68Nfs*43 | Frame Shift Ins (INS) | VAF 51/149 reads (34%) | called by mutect2, pindel, varscan2
